Surgical pathology report (de-identified scan), TCGA case TCGA-HF-A5NB, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HF-A5NB-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Adenocarcinoma, intestinal*
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Stomach (antrum)
Tumour Size (cm)	7.5
Histology	Adenocarcinoma, intestinal*
Grade/Differentiation	III
Pathological T	T4a
Pathological N	N3a
Clinical M	M0
Histology Comments	Tumour invades into duodenum. Omentum also involved. *Histology: Intestinal adenocarcinoma with a mucinous component which comprises < 50% of the tumour.

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3
Path Adenocarcinoma, w/mixed subtypes 8255/3
C&CF Adenocarcinoma, mucinous NOS 8480/3
Site Stomach, gastric antrum C16.3
JW 2/11/13

Source: NCI Genomic Data Commons file dc85443c-bd24-487a-aed1-8dab17b94c33 (TCGA-HF-A5NB.E5A60EAE-914A-4426-8F9A-E303633EB144.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).